Surgical pathology report (de-identified scan), TCGA case TCGA-LG-A6GG, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Hartford Hospital, specimen TCGA-LG-A6GG-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

DATE OBTAINED:
DATE RECEIVED:
DATE REPORTED:

CC:

DIAGNOSIS

ICD O-3

#1- RESECTION, LIVER (SEGMENT 3): HEPATOCELLULAR CARCINOMA-

Tumor type:	Hepatocellular carcinoma
Histologic grade:	Moderately differentiated; nuclear grade (II)
Tumor size:	8.5cm.
Tumor multifocality:	Unifocal
Vascular invasion:	Microvascular invasion (focal)
Hepatic capsule:	Negative (1.8 cm); subcapsular hemorrhage
Local extension:	Confined to the liver
Margins:	Hepatic parenchymal transection margin- negative (tumor-1.5 cm from staple line margin)
Lymph nodes:	Not present
Other findings:	Micronodular cirrhosis
AJCC stage:	pT2 NX Stage II

*Carcinoma, hepatocellular NOS
Site: Liver C22.0
8/17/13*

Electronically Signed Out

COMMENT

88309, 88331x2

Clinical Diagnosis and History:

Liver tumor

Tissue(s) Submitted:

SEGMENT 3 LIVER LESION

Gross Description:

The specimen is received fresh for intraoperative consultation labeled with patient name designated segment 3 liver lesion and consists of a 292 gram, 11.5 x 8.0 x 6.5 cm intact segment of liver with a single stapled margin. The capsular surface is red brown, intact and shaggy. The resection margin is inked and the specimen is serially sectioned to reveal an 8.5 x 7.0 x 5.5 cm soft tan brown well defined mass measuring 1.5 cm from the stapled margin with surrounding dark red subcapsular hemorrhage. The uninvolved liver parenchyma is tan brown and granular. No other discrete lesions are identified. Representative sections are submitted as follows:

1AFS: soft tissue frozen section remnant
1BFS: mass frozen section remnant

[page 2 of 2]
Surgical Pathology Report

1C-1E: mass to margin
1F-1H: mass to subcapsular hemorrhage
1I-1J: mass

Intraoperative Consult Diagnosis

1A/FSDX: GROSS RESECTION MARGIN NEGATIVE (1.8 CM TUMOR TO MARGIN); HEPATOCELLULAR CARCINOMA.

Criteria	hw 5/21/13	Yes	No
Hx/UA Discrepancy			✓
Reviewer Initials	BTM	Reviewed: 5/20/13	

END OF REPORT

Source: NCI Genomic Data Commons file f69e8656-1be1-484c-b20d-e4ef3bb54f87 (TCGA-LG-A6GG.A7F1EA5C-5797-42D1-AD35-E2E529B26409.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).